Somatic mutation profile of tumor specimen TCGA-DD-A73F-01A (aliquot TCGA-DD-A73F-01A-11D-A32G-10) from TCGA case TCGA-DD-A73F, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 77.3 years (28,234 days).
Specimen TCGA-DD-A73F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16dc014a-c6e0-442c-838c-fbb1a8c02125.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A73F-10A (Blood Derived Normal), aliquot TCGA-DD-A73F-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a58e3a8-90fc-45c1-858a-c8f21a48f052

The open-access MAF lists 76 somatic variants for this specimen: 52 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 46, Silent 24, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADACL3 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.329); catalogued as rs748929112, COSV100206829, COSV60198875; called by muse, mutect2, varscan2
- ACACB | c.4674C>A p.F1558L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV58133864; called by muse, mutect2, varscan2
- ACO2 | c.41C>G p.A14G | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV53442650; called by muse, mutect2, varscan2
- ALMS1 | c.10978G>A p.V3660M | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as COSV52509106; called by muse, mutect2, varscan2
- ATP4A | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (0.967); catalogued as rs567483940, COSV52867667; called by muse, mutect2, varscan2
- AUP1 | c.899T>A p.L300Q | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV51207299; called by muse, mutect2
- CARD10 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 75/140 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as rs753304481, COSV52654931; called by muse, mutect2, varscan2
- CEP70 | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.085); catalogued as COSV53875547; called by muse, mutect2, varscan2
- CXorf38 | c.457A>C p.K153Q | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.347); catalogued as COSV59947534; called by muse, mutect2, varscan2
- DPF2 | c.1048C>G p.R350G | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV52889184, COSV52889268; called by muse, mutect2
- EBF1 | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV58168973, COSV58177101; called by muse, mutect2, varscan2
- F10 | c.425A>T p.E142V | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as COSV65021615; called by muse, mutect2, varscan2
- FOXL2NB | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.651); catalogued as rs530645680, COSV57726947; called by muse, mutect2, varscan2
- GET4 | c.505T>G p.S169A | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV56254377; called by muse, mutect2, varscan2
- GPR101 | c.362C>A p.T121N | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV53238762; called by muse, mutect2, varscan2
- ICAM5 | c.1385G>T p.R462L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.984); catalogued as COSV99703585; called by muse, mutect2
- IGDCC3 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1405532603, COSV60077454; called by muse, mutect2, varscan2
- INO80 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.227); catalogued as COSV62737840, COSV62741639; called by muse, mutect2, varscan2
- IRX1 | c.484A>G p.M162V | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV57359319; called by muse, mutect2, varscan2
- KCNN4 | c.442G>C p.G148R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as COSV53455387; called by muse, mutect2, varscan2
- MAP4K3 | c.2532A>T p.R844S | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.156); catalogued as rs1388854176, COSV55712719; called by muse, mutect2, varscan2
- MC3R | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1286756644, COSV54762849; called by muse, mutect2, varscan2
- MGA | c.4031G>A p.W1344* | Nonsense Mutation (SNP) | VAF 33/94 reads (35%) | catalogued as COSV54953317; called by muse, mutect2, varscan2
- MTCL1 | c.2183G>A p.R728H (on ENST00000306329 / NM_001378206.1; = p.R368H on NM_015210.4) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1424023757, COSV60405774, COSV60408305; called by muse, mutect2, varscan2
- MUC16 | c.12532T>C p.S4178P | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.354); catalogued as COSV67463359; called by muse, mutect2, varscan2
- MYT1L | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.058); catalogued as rs573013583, COSV101221064, COSV67719184; called by muse, mutect2, varscan2
- NDST4 | c.1801G>C p.G601R | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52118437; called by muse, mutect2, varscan2
- OR14A16 | c.881T>C p.I294T | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs756063893, COSV62926594; called by muse, mutect2
- PCDHA12 | c.28G>C p.G10R | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV56498291; called by muse, mutect2, varscan2
- PIGB | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.758); catalogued as rs1259418062, COSV51241632; called by muse, mutect2
- PIK3C2B | c.4885C>T p.R1629* | Nonsense Mutation (SNP) | VAF 48/114 reads (42%) | catalogued as rs376434764; called by muse, mutect2, varscan2
- PLA2G4C | c.376G>C p.A126P | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62785302, COSV62785314; called by muse, mutect2, varscan2
- PLA2R1 | c.2129C>A p.A710D | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.677); catalogued as rs1177930274, COSV51778229; called by muse, mutect2, varscan2
- PRPF4 | c.560+1G>T p.X187_splice (on ENST00000374198 / NM_001322267.2; = p.X188_splice on NM_004697.5) | Splice Site (SNP) | VAF 7/130 reads (5%) | catalogued as COSV65252604; called by muse, mutect2
- PRRT1 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.926); catalogued as COSV52998205, COSV99053431, COSV99278698; called by muse, mutect2, varscan2
- PTPN13 | c.5938G>A p.A1980T (on ENST00000411767 / NM_080683.3; = p.A1961T on NM_006264.3) | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1480125548, COSV57406864; called by muse, mutect2, varscan2
- RANBP3L | c.1086G>T p.K362N | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.258); catalogued as COSV56955439; called by muse, mutect2, varscan2
- RPE65 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV52015663; called by muse, mutect2, varscan2
- RPH3A | c.254A>T p.N85I (on ENST00000389385 / NM_001143854.2; = p.N81I on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV66990949; called by muse, mutect2, varscan2
- SLC12A1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1359543179, COSV57709402; called by muse, mutect2, varscan2
- SLC27A6 | c.1535A>T p.Y512F | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52482705; called by muse, mutect2, varscan2
- SLC5A11 | c.1603A>C p.T535P | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV61741419; called by muse, mutect2
- ST18 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs147121734, COSV52493113, COSV52503394; called by muse, mutect2, varscan2
- TDRD1 | c.3137T>C p.L1046P | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52590308; called by muse, mutect2, varscan2
- TENT5D | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57636457; called by muse, mutect2, varscan2
- TKTL1 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54212799; called by muse, mutect2, varscan2
- TM9SF3 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV64457360, COSV64458139; called by muse, mutect2, varscan2
- USP1 | c.1867A>C p.K623Q | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.1); catalogued as COSV52004137; called by muse, mutect2, varscan2
- ZFYVE27 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as rs767402454, COSV61746631; called by muse, mutect2, varscan2
- AC006059.2 | c.1256_1274del p.E419Vfs*18 | Frame Shift Del (DEL) | VAF 17/81 reads (21%) | called by mutect2, pindel
- CCDC88B | c.2395G>T p.A799S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2
- DMXL2 | c.7603+2_7603+10del p.X2535_splice | Splice Site (DEL) | VAF 47/218 reads (22%) | called by mutect2, pindel, varscan2
- ALYREF | c.667C>A p.R223= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as rs1019938563, COSV100485858; called by muse, mutect2
- CAMK2N1 | c.42C>A p.P14= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV66757424; called by muse, mutect2, varscan2
- CAMTA1 | c.852C>T p.R284= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as COSV57898686; called by muse, mutect2, varscan2
- CHRNA4 | c.1710C>T p.G570= | Silent (SNP) | VAF 55/118 reads (47%) | catalogued as rs1259026322, COSV64719367; called by muse, mutect2, varscan2
- DIPK2B | c.1113G>A p.Q371= | Silent (SNP) | VAF 50/141 reads (35%) | catalogued as COSV101211688, COSV67641124; called by muse, mutect2, varscan2
- FILIP1 | c.186T>A p.S62= | Silent (SNP) | VAF 66/233 reads (28%) | catalogued as COSV52728848; called by muse, mutect2, varscan2
- FRAS1 | c.1557T>C p.G519= | Silent (SNP) | VAF 38/124 reads (31%) | catalogued as COSV53607837; called by muse, mutect2, varscan2
- GDF10 | c.1074C>T p.D358= | Silent (SNP) | VAF 47/148 reads (32%) | catalogued as rs374890077; called by muse, mutect2, varscan2
- GJA8 | c.777C>T p.S259= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as rs959340023, COSV53788833; called by muse, mutect2, varscan2
- HUWE1 | c.9292C>A p.R3098= | Silent (SNP) | VAF 6/128 reads (5%) | catalogued as COSV53344338; called by muse, mutect2
- KRTAP13-2 | c.384A>G p.R128= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as rs769694331, COSV67761999; called by muse, mutect2, varscan2
- LNPEP | c.2304C>T p.A768= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV51477795, COSV51480730; called by muse, mutect2
- MINK1 | c.888G>A p.R296= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV61789965; called by muse, mutect2, varscan2
- NLRP4 | c.1038C>T p.I346= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV56713054; called by muse, mutect2, varscan2
- PHAX | c.822C>A p.L274= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV52551100; called by muse, mutect2, varscan2
- PTPRB | c.18C>T p.A6= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs773041705, COSV54239836; called by muse, mutect2, varscan2
- SLC29A1 | c.366G>T p.V122= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV57578217; called by muse, mutect2, varscan2
- SLITRK1 | c.924T>A p.G308= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as COSV65675429; called by muse, mutect2, varscan2
- SLTM | c.714T>C p.A238= | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as COSV51054019; called by muse, mutect2, varscan2
- SP4 | c.2103T>C p.H701= | Silent (SNP) | VAF 51/149 reads (34%) | catalogued as rs1268415400, COSV56022497; called by muse, mutect2, varscan2
- TRIL | c.1959G>A p.G653= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV59867029; called by muse, mutect2
- ZC3HAV1 | c.1659G>A p.E553= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV54295477; called by muse, mutect2, varscan2
- ZER1 | c.321G>A p.E107= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV52565555; called by muse, mutect2, varscan2
- ZNF607 | c.1254G>A p.E418= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV67696772; called by muse, mutect2, varscan2
